Somatic mutation profile of tumor specimen 0DR6YE from CCDI case PBCFKC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.9 years (5,079 days).
Specimen 0DR6YE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94175bac-bff4-48ba-be78-942400bca9dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR7YD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/011650cf-317d-4dd6-b969-204371eeac3c

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.39397A>G p.T13133A (on ENST00000591111; = p.T5709A on NM_003319.4) | Missense Mutation (SNP) | VAF 93/2281 reads (4%) | PolyPhen probably damaging (0.994); catalogued as rs748139496, COSV100614356; called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 72/2068 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- AC068580.4 | c.459G>A p.Q153= | Silent (SNP) | VAF 23/467 reads (5%) | called by muse, mutect2
- SPART | c.945A>G p.L315= | Silent (SNP) | VAF 64/2071 reads (3%) | called by muse, mutect2
- HYOU1 | c.185+33C>T | Intron (SNP) | VAF 30/596 reads (5%) | catalogued as rs782179843; called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 14/376 reads (4%) | called by muse, mutect2
